Somatic mutation profile of tumor specimen ALCH-B4YS-TTP1-A (aliquot ALCH-B4YS-TTP1-A-2-0-D-A83F-36) from ALCHEMIST case ALCH-B4YS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.7 years (26,935 days).
Specimen ALCH-B4YS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af293514-b54d-41db-bfdf-eae71b1abb19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4YS-NB1-A (Blood Derived Normal), aliquot ALCH-B4YS-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f57e89a8-189c-4446-8966-43ecc3490dce

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 6, Intron 4, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 105/424 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- EXTL3 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs371352200; called by muse, mutect2
- FAM131B | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV68126821; called by muse, mutect2, varscan2
- HECW2 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 37/181 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53649834; called by muse, mutect2, varscan2
- MACC1 | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 81/324 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV100256428; called by muse, mutect2, varscan2
- NTRK3 | c.2286G>T p.E762D (on ENST00000360948 / NM_001012338.2; = p.E748D on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/556 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1361372348, COSV62305415; called by muse, mutect2, varscan2
- PLCL1 | c.2438C>T p.T813M | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748546401, COSV70827442; called by muse, mutect2, varscan2
- PPP1R13B | c.85C>G p.R29G | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs557115649, COSV52454663; called by muse, mutect2, varscan2
- RBM10 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 135/254 reads (53%) | catalogued as COSV61307739; called by muse, mutect2, varscan2
- THEMIS2 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs775104517; called by mutect2, varscan2
- ADAM28 | c.2056A>G p.I686V | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.12256A>G p.K4086E | Missense Mutation (SNP) | VAF 77/377 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- BOD1L1 | c.2468A>G p.E823G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- BRAP | c.1327A>T p.T443S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- C11orf96 | c.1028del p.P343Rfs*29 (on ENST00000339446; = p.P30Rfs*29 on NM_001145033.2) | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- CDKN2C | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 142/525 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- COL3A1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 137/483 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAZAP1 | c.91del p.S31Pfs*7 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | called by mutect2, pindel, varscan2
- DLG3 | c.42_45del p.Y14* | Frame Shift Del (DEL) | VAF 50/104 reads (48%) | called by mutect2, pindel, varscan2
- ETV1 | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 183/763 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- GGT5 | c.548T>A p.F183Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, varscan2
- GRM5 | c.2168A>T p.Y723F | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- H2AC8 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- NRG2 | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTP4A1 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SRD5A3 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TNXB | c.7369C>G p.L2457V (on ENST00000647633; = p.L2210V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VPS13C | c.94T>A p.W32R | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZXDA | c.227C>G p.P76R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DIP2A | c.2139C>T p.V713= | Silent (SNP) | VAF 12/392 reads (3%) | called by muse, mutect2
- FBL | c.156C>T p.G52= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs573913896, COSV55683442; called by muse, mutect2
- GPAA1 | c.1542C>T p.A514= | Silent (SNP) | VAF 34/221 reads (15%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.171G>T p.R57= | Silent (SNP) | VAF 76/1288 reads (6%) | catalogued as rs544378490; called by muse, mutect2
- MIB1 | c.1833A>G p.A611= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2
- SERPINF2 | c.696C>T p.L232= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as rs1451411418; called by muse, mutect2, varscan2
- ACAD8 | c.706-49C>A | Intron (SNP) | VAF 48/176 reads (27%) | called by muse, mutect2, varscan2
- ITGA2 | c.1807-13C>T | Intron (SNP) | VAF 74/534 reads (14%) | catalogued as rs1443166667; called by muse, mutect2, varscan2
- MPRIP | c.2164-4423T>C | Intron (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- NDUFS2 | c.780+18G>A | Intron (SNP) | VAF 118/627 reads (19%) | called by muse, mutect2, varscan2
